Surgical pathology report (de-identified scan), TCGA case TCGA-36-1568, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site BC Cancer Agency, specimen TCGA-36-1568-01A (Primary Tumor).

[page 1 of 2]
Final Diagnosis:

A,B. Bilateral ovaries and tubes:

- 1) Invasive high-grade carcinoma ovarian consistent with serous carcinoma with small foci of clear cell change.
- 2) Silverberg grade 3/3 (Nuclear score 3; mitotic score 2; architecture score 3).
- 3) Extraovarian pelvic spread present-6 cm deposit attached to the left fallopian tube.
- 4) No definite lymphatic invasion identified.

C. Uterus and cervix:

- 1) Inactive endometrium.
- 2) Leiomyoma.
- 3) Benign endometrial and endocervical polyp.
- 4) Benign cervical tissue.

D. [REDACTED] pelvic wash shows reactive mesothelial cells, inflammatory cells; no malignant cells seen.

E. TMN stage: pT2a, Nx, Mx.

F. [REDACTED]

Specimens Received:

- A: left ovary + tube
B: right tube + ovary
C: uterus + cervix

Gross Description:

Specimen is received in three containers each labelled with the patient's name.

Container "A" is labelled "left ovary and tube" and consists of two lesions connected together by fallopian tube-like structure. It weighs 92 g. The maximum tumour extension of one of the lesions is 6 cm and the other is 4 cm. The fallopian tube measures 5.5 x .7 cm. Intraoperative diagnosis done by [REDACTED]. On cut section, the first lesion (6 cm) is composed mainly of a solid yellowish nodular lesion. The second one is composed of multiloculated cysts and a 2 cm yellowish nodular solid area. The cyst is filled with serous clear fluid.

Representative sections are submitted as follows:

- "A1" -frozen section
"A2" -representative from the first lesion with the fallopian tube attachment
"A3-A4" -representative from the rest of the first lesion
"A5" -representative from the fallopian tube with the second lesion
"A6-A8" -representative from the second lesion
"A9" -representative from the fallopian tube.

[page 2 of 2]
Container "B" is labelled "right tube and ovary" and consists of a 4.5 x .7 cm fallopian tube-like structure attached to a yellowish nodular lesion. This lesion measures 7 x 4 x 2.5 cm. On cut section, it shows multiloculated cysts, some filled by clear serous fluid and others by mucoid material, and a 3.5 cm solid whitish nodular lesion.

Representative sections are submitted as follows:

"B1" -from the fallopian tube

"B2-B8" -representative from the ovarian mass.

A part of the tumour of specimen B is submitted for tumour bank.

Container "C" is labelled "uterus and cervix". The uterus weighs 91 g and measures 5.5 cm from the superior to inferior, 6 cm from anterior to posterior, and 5 cm from side to side. The anterior serosal surface shows a 3.5 cm subserosal nodule, otherwise unremarkable. The cervix measures 4 x 4 x 2 cm which is unremarkable. The anterior myometrial wall shows a whitish whorled lesion, which measures 3 x 2.5 x 2 cm. The anterior endometrium appears unremarkable. The posterior myometrial wall shows a .8 cm whitish whorled lesion, otherwise unremarkable. Two posterior lower uterine segment polyps are identified which measure .7 and 1.5 cm respectively. The rest of the posterior endometrium appears unremarkable.

Representative sections are submitted as follows:

"C1-C2" -from the anterior and posterior cervix respectively

"C3-C4" -representative from the anterior uterine wall

"C5-C6" -representative from the anterior myometrium lesion

"C7-C8" -representative from the posterior uterine wall

"C9-C10" -representative from the posterior endometrial polyps

"C11" -representative from the posterior myometrium lesion

"C12" -representative from the cul-de-sac.

Intraoperative Consultation:

FSA/1

Gross Description: 1. Max. 6 cm

2. " 4 cm

Source: NCI Genomic Data Commons file 1b6ff15b-48a9-4e8a-8127-c2c5c5a4d01e (TCGA-36-1568.DAD4BBDC-0156-48C2-A975-27CCFB9152A3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).